Somatic mutation profile of tumor specimen 0DS10B from CCDI case PBCHMY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DS10B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99897be9-dcb4-4daf-9aa0-32e40473852b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0ZF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12dd36d5-e388-486a-bf9d-aa1194796be9

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD7 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 112/596 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58287867; called by muse, mutect2, varscan2
- PLAAT4 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs368947257; called by muse, mutect2, varscan2
- MYO5A | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 183/1347 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLTM | c.3093G>T p.P1031= | Silent (SNP) | VAF 191/543 reads (35%) | catalogued as rs199687843; called by muse, mutect2, varscan2
- TENM3 | c.7473G>A p.T2491= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as rs529786665; called by muse, mutect2, varscan2
- AL160313.1 | n.286G>A | RNA (SNP) | VAF 3/26 reads (12%) | catalogued as rs796493732; called by muse, varscan2
- MTMR3 | c.3337-81T>A | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
